Somatic mutation profile of tumor specimen TCGA-C4-A0EZ-01A (aliquot TCGA-C4-A0EZ-01A-21D-A10S-08) from TCGA case TCGA-C4-A0EZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,202 days).
Specimen TCGA-C4-A0EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838eeb66-ac96-4cec-99b0-1eff4607bab8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C4-A0EZ-10A (Blood Derived Normal), aliquot TCGA-C4-A0EZ-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e1b7a27-edf5-4a0c-8dff-6ab64fc67a89

The open-access MAF lists 217 somatic variants for this specimen: 162 protein-altering or splice-affecting, 49 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 49, Nonsense Mutation 18, Splice Site 5, Intron 4, Frame Shift Del 3, Splice Region 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTM1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 28/143 reads (20%) | catalogued as rs132630306, CM970990, COSV60334496, COSV60334771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as rs119456963, CM081371, CM161065, COSV58629944; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 60/60 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100589079; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs201573079, COSV65891957; called by muse, mutect2, varscan2
- ADAMTSL2 | c.91-1G>A p.X31_splice | Splice Site (SNP) | VAF 46/138 reads (33%) | catalogued as COSV63203978; called by muse, mutect2, varscan2
- ADCY4 | c.2192C>A p.S731Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60254005; called by muse, mutect2, varscan2
- ANKMY1 | c.2779+1G>A p.X927_splice | Splice Site (SNP) | VAF 45/104 reads (43%) | catalogued as rs998337764, COSV56033593; called by muse, mutect2, varscan2
- ANKRD12 | c.1547G>A p.R516K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV50824209; called by muse, mutect2, varscan2
- APCDD1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs916340314, COSV62372438; called by muse, mutect2, varscan2
- ARHGAP17 | c.54-1G>A p.X18_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV51506749, COSV99254153; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV63437833; called by muse, mutect2, varscan2
- ATP8B3 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs780575598, COSV59541507; called by muse, mutect2, varscan2
- ATRX | c.7211G>C p.C2404S | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as COSV64876037; called by muse, mutect2, varscan2
- BCORL1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | catalogued as COSV99501197; called by muse, mutect2, varscan2
- BPTF | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58836528; called by muse, mutect2, varscan2
- BRD2 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100875870; called by muse, mutect2, varscan2
- BRINP3 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66523069; called by muse, mutect2, varscan2
- C14orf93 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs778432140, COSV54440944; called by muse, mutect2, varscan2
- C1orf198 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV64175285; called by muse, mutect2
- CACNA1B | c.2091C>A p.N697K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53124695; called by muse, mutect2, varscan2
- CACNA2D3 | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs746696198, COSV55535797; called by muse, mutect2, varscan2
- CD101 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV56717799; called by muse, mutect2, varscan2
- CD22 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs138631884; called by muse, mutect2, varscan2
- CD99L2 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.892); catalogued as COSV60936043; called by muse, mutect2, varscan2
- CDH12 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.563); catalogued as COSV66402935; called by muse, mutect2, varscan2
- CDK12 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71000510; called by muse, mutect2, varscan2
- CDK5 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52521837; called by muse, mutect2, varscan2
- CDK8 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67420549; called by muse, mutect2, varscan2
- CEACAM4 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as rs559349148, COSV55731540, COSV55732439; called by muse, mutect2, varscan2
- CEMIP2 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV65484521; called by muse, mutect2, varscan2
- CFH | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62777305; called by muse, mutect2, varscan2
- CHD7 | c.951C>G p.N317K | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.528); catalogued as COSV71109949; called by muse, mutect2, varscan2
- CNBD1 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV72976079; called by muse, mutect2, varscan2
- COL5A2 | c.744+1G>A p.X248_splice | Splice Site (SNP) | VAF 25/48 reads (52%) | catalogued as COSV66409362; called by muse, mutect2, varscan2
- COL9A2 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.988); catalogued as COSV65607455; called by muse, mutect2, varscan2
- CPNE9 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56068365; called by muse, mutect2, varscan2
- CTSA | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV51941948; called by muse, mutect2, varscan2
- DCLRE1A | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 60/163 reads (37%) | catalogued as COSV100800290; called by muse, mutect2, varscan2
- DLL1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV100816217; called by muse, mutect2, varscan2
- DMXL2 | c.4670C>T p.S1557L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as rs765137113, COSV51845608; called by muse, mutect2, varscan2
- DNAH17 | c.9268G>A p.E3090K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs544426335, COSV67753687; called by muse, mutect2, varscan2
- DNAH5 | c.11422C>T p.Q3808* | Nonsense Mutation (SNP) | VAF 47/210 reads (22%) | catalogued as COSV54238630; called by muse, mutect2, varscan2
- DNAH5 | c.9266C>T p.S3089L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759831156, COSV54208359, COSV54225546; called by muse, mutect2, varscan2
- DNAH5 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150601733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG4 | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs745426729, COSV100356225, COSV57389096; called by muse, mutect2
- FAM227B | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV54810373; called by muse, mutect2, varscan2
- FAM47A | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374052739, COSV60496340; called by muse, mutect2, varscan2
- FAM71C | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV60943153; called by muse, mutect2, varscan2
- FAM83C | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.685); catalogued as rs141772980; called by muse, mutect2, varscan2
- FAT4 | c.6700C>T p.R2234* | Nonsense Mutation (SNP) | VAF 46/131 reads (35%) | catalogued as COSV58715243; called by muse, mutect2, varscan2
- FBN3 | c.8224G>A p.V2742I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs372313415; called by muse, mutect2, varscan2
- FBXL20 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.723); catalogued as COSV52897137, COSV52898691; called by muse, mutect2, varscan2
- FLG2 | c.4667C>G p.S1556C | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV101165569, COSV66168460; called by muse, mutect2, varscan2
- FOXF1 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV52285922; called by muse, mutect2, varscan2
- FOXRED2 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs775500624, COSV53399783; called by muse, varscan2
- FOXRED2 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53399797; called by muse, varscan2
- FRMPD3 | c.4883G>T p.R1628L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV52189908; called by muse, mutect2, varscan2
- FTHL17 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV63266830; called by muse, mutect2, varscan2
- GABRA6 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 65/115 reads (57%) | catalogued as COSV99195306; called by muse, mutect2, varscan2
- GDI2 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV66334715; called by muse, mutect2, varscan2
- GNG3 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV53654973; called by muse, mutect2, varscan2
- GRIA4 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56894595; called by muse, mutect2, varscan2
- GRIA4 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs761018528, COSV56881287; called by muse, varscan2
- GRIK2 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59733555; called by muse, mutect2, varscan2
- GRM5 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV59601513, COSV59603490; called by muse, mutect2, varscan2
- HDC | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV51069879; called by muse, mutect2, varscan2
- HELZ2 | c.4975G>A p.G1659S (on ENST00000467148 / NM_001037335.2; = p.G1090S on NM_033405.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as rs763147564, COSV71295875; called by muse, mutect2, varscan2
- IFITM5 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV66888107; called by muse, mutect2, varscan2
- IQGAP2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.058); catalogued as rs1166947612, COSV57172776; called by muse, mutect2, varscan2
- ISM2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 130/293 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV53634928; called by muse, mutect2, varscan2
- KATNA1 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59502260; called by muse, mutect2, varscan2
- KCNV1 | c.1376C>A p.A459D | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV52085932; called by muse, mutect2, varscan2
- KIAA1210 | c.1850T>C p.M617T | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV68176974; called by muse, mutect2, varscan2
- KLHL13 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV53247164; called by muse, mutect2, varscan2
- LCN9 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1279045750, COSV52990645; called by muse, mutect2, varscan2
- LRATD2 | c.236A>C p.H79P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV59230072; called by muse, mutect2, varscan2
- LRRC8C | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV64997578; called by muse, mutect2, varscan2
- MAP3K1 | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 47/83 reads (57%) | catalogued as rs1246045657, COSV68129019; called by muse, mutect2, varscan2
- MARCHF5 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62769605; called by muse, mutect2, varscan2
- MBTPS1 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | catalogued as COSV58570475, COSV58571565; called by muse, mutect2, varscan2
- MCF2L | c.3283G>A p.V1095I (on ENST00000375608; = p.V1063I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV56177339; called by muse, mutect2, varscan2
- MKRN3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs779114986, COSV58809720; called by muse, mutect2, varscan2
- MMEL1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs756046469, COSV56521214; called by muse, mutect2, varscan2
- MUC3A | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT deleterious, low confidence (0); catalogued as rs796137574, COSV60214851; called by muse, mutect2, varscan2
- MUC5B | c.11668T>C p.W3890R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV71591907; called by muse, mutect2, varscan2
- MXRA5 | c.4231A>G p.K1411E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54233931; called by muse, mutect2, varscan2
- MYH7 | c.5323A>G p.T1775A | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62518860; called by muse, mutect2
- MYH7B | c.2646C>G p.F882L | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV53419650; called by muse, mutect2, varscan2
- MYOF | c.1334+1G>A p.X445_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as rs1207826442, COSV100826195; called by muse, mutect2, varscan2
- MZF1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV53041462; called by muse, mutect2, varscan2
- NCBP2L | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64943896; called by muse, mutect2, varscan2
- NEK10 | c.3319C>T p.R1107C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs147586444; called by muse, mutect2, varscan2
- NEXMIF | c.2303C>G p.S768* | Nonsense Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99282150; called by muse, mutect2, varscan2
- NLGN1 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as rs200519167, COSV64332420; called by muse, mutect2, varscan2
- NLRC3 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs199854307; called by muse, mutect2, varscan2
- NOS2 | c.1714A>G p.M572V | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1453944946, COSV58223523; called by muse, mutect2, varscan2
- NOTUM | c.1331A>G p.H444R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV68826080; called by muse, mutect2, varscan2
- OR10G8 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70908508; called by muse, mutect2, varscan2
- OR51G2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV58992786; called by muse, mutect2, varscan2
- OR5AC2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs769617683, COSV62279168; called by muse, mutect2, varscan2
- OSBPL3 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV57656162; called by muse, mutect2, varscan2
- OTUD7A | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61038370, COSV61044043; called by muse, mutect2, varscan2
- PCDHAC1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53847925; called by muse, mutect2, varscan2
- PLCG1 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.241); catalogued as COSV54818183; called by muse, mutect2, varscan2
- PLCL1 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 67/71 reads (94%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs373797233; called by muse, mutect2, varscan2
- PREX1 | c.4946G>A p.R1649H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1302009672, COSV100906884; called by muse, mutect2
- PROS1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 105/175 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs370129669, COSV67774805; called by muse, mutect2, varscan2
- R3HDM2 | c.1767G>C p.Q589H | Missense Mutation (SNP) | VAF 112/193 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61288257; called by muse, mutect2, varscan2
- RAB13 | c.123C>T p.I41= | Splice Region (SNP) | VAF 10/77 reads (13%) | catalogued as COSV63933655, COSV63933723; called by muse, mutect2, varscan2
- RGS22 | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100693922, COSV62662696; called by muse, mutect2, varscan2
- RIOK2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1383670790, COSV51612508; called by muse, mutect2
- RNF135 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs1359536712, COSV60433433, COSV60433450; called by muse, mutect2, varscan2
- RNF141 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV56416940; called by muse, mutect2, varscan2
- RPS2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV51910120, COSV51910970; called by muse, mutect2, varscan2
- RSPRY1 | c.838A>G p.N280D | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68027615; called by muse, mutect2, varscan2
- S100G | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV63722415; called by muse, mutect2, varscan2
- SAGE1 | c.348G>T p.R116S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV100186823, COSV61013141; called by muse, mutect2, varscan2
- SAMSN1 | c.828A>G p.I276M | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV104374929, COSV53471008; called by muse, mutect2, varscan2
- SCN7A | c.4015C>G p.L1339V | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV69271176; called by muse, mutect2, varscan2
- SDK2 | c.3562C>T p.Q1188* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as rs1299414090, COSV66199872; called by muse, mutect2, varscan2
- SESN1 | c.1333G>C p.E445Q (on ENST00000356644 / NM_001199933.1; = p.E504Q on NM_014454.3) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV57420736; called by muse, mutect2, varscan2
- SH2D1A | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV63578768; called by muse, mutect2, varscan2
- SIM1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV53491759; called by muse, mutect2, varscan2
- SLC35F4 | c.1379C>T p.T460I (on ENST00000339762 / NM_001352015.2; = p.T424I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as rs761222985, COSV100334321, COSV60264543; called by muse, mutect2, varscan2
- SLC39A5 | c.772T>C p.C258R | Missense Mutation (SNP) | VAF 125/208 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763071118, COSV57191621; called by muse, mutect2, varscan2
- SLC4A5 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 88/459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780268146, COSV61027244; called by muse, mutect2, varscan2
- SNX32 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs754175699, COSV57449445; called by muse, mutect2, varscan2
- SORCS3 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV63809283; called by muse, mutect2, varscan2
- SPANXN3 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65140285; called by muse, mutect2, varscan2
- SPIRE2 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV65554717, COSV65555572; called by muse, mutect2, varscan2
- SPTA1 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246806960, COSV100934865, COSV63752526; called by muse, mutect2, varscan2
- STAT4 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.64); catalogued as COSV100636214, COSV61829574; called by muse, mutect2
- SYNE1 | c.4987G>A p.E1663K (on ENST00000367255 / NM_182961.4; = p.E1670K on NM_033071.3) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV54971693; called by muse, mutect2, varscan2
- SYT3 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs1568416291, COSV58896392; called by muse, mutect2, varscan2
- TBC1D1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV54713306; called by muse, mutect2, varscan2
- TCN2 | c.753G>A p.Q251= | Splice Region (SNP) | VAF 47/75 reads (63%) | catalogued as COSV53191322; called by muse, mutect2, varscan2
- THEMIS | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV64070941; called by muse, mutect2, varscan2
- TMC8 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100573824; called by muse, mutect2, varscan2
- TP53BP1 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs748353199, COSV55500587; called by muse, mutect2, varscan2
- TRIM68 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100331850; called by muse, mutect2, varscan2
- TYW1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 59/183 reads (32%) | catalogued as rs769154282, COSV62753704; called by muse, mutect2, varscan2
- UBE2J2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs183303737, COSV59572230; called by muse, mutect2, varscan2
- USF3 | c.6346C>G p.P2116A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57072305; called by muse, mutect2, varscan2
- USP10 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs369176775; called by muse, mutect2, varscan2
- USP29 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54142327; called by muse, mutect2, varscan2
- VWCE | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV57112271; called by muse, mutect2, varscan2
- XPO7 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV53014427; called by muse, mutect2, varscan2
- XPR1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 230/416 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62556340; called by muse, mutect2, varscan2
- ZNF224 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | catalogued as COSV100425585; called by muse, mutect2, varscan2
- ZNF273 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as rs747886666, COSV60398495; called by muse, mutect2, varscan2
- ZNF292 | c.7661C>T p.S2554L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV60539085; called by muse, mutect2, varscan2
- ZNF296 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV54319592; called by muse, mutect2, varscan2
- ZNF419 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55659478; called by muse, mutect2, varscan2
- ZNF608 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60437445; called by muse, mutect2, varscan2
- ZNF804A | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV56437295; called by muse, mutect2, varscan2
- CSPG5 | c.474_495delinsGG p.D159Gfs*44 | Frame Shift Del (DEL) | VAF 41/67 reads (61%) | called by pindel, varscan2*
- FIGN | c.2141_2148del p.S714Yfs*14 | Frame Shift Del (DEL) | VAF 27/32 reads (84%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.164T>C p.L55S | Missense Mutation (SNP) | VAF 130/131 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IGKV2-28 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.047); called by mutect2, varscan2
- MAGEB4 | c.583del p.L195Ffs*7 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- POLE2 | c.42C>G p.F14L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABTB2 | c.2355C>T p.T785= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs1225301988, COSV54387758; called by muse, mutect2, varscan2
- AFF2 | c.2103C>T p.G701= | Silent (SNP) | VAF 40/209 reads (19%) | catalogued as COSV53988067; called by muse, mutect2, varscan2
- ARHGAP32 | c.1185C>T p.F395= (on ENST00000310343 / NM_001378025.1; = p.F46= on NM_014715.4) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV59847185; called by muse, mutect2, varscan2
- ARID4B | c.1806C>T p.V602= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV51602630; called by muse, mutect2, varscan2
- ATAD3A | c.729G>A p.A243= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs549678655, COSV59233195; called by muse, mutect2, varscan2
- ATF6B | c.12G>C p.L4= | Silent (SNP) | VAF 55/90 reads (61%) | catalogued as COSV64322444; called by muse, mutect2, varscan2
- BAZ1B | c.3468C>T p.I1156= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV59990852; called by muse, mutect2, varscan2
- C1GALT1 | c.516G>A p.T172= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs138478625; called by muse, mutect2, varscan2
- C4orf50 | c.471C>T p.L157= (on ENST00000324058; = p.L1389= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV60688415; called by muse, mutect2
- CDK18 | c.219C>T p.L73= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV63727378; called by muse, mutect2
- CHD5 | c.1509G>A p.L503= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1474450361, COSV52413632; called by muse, mutect2, varscan2
- DCHS1 | c.1596G>T p.T532= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as COSV55034918; called by muse, mutect2, varscan2
- DPPA2 | c.168G>A p.K56= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs773072062, COSV72118054; called by muse, mutect2, varscan2
- EID3 | c.525C>T p.F175= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as COSV61597782; called by muse, mutect2, varscan2
- EP400 | c.2985C>G p.L995= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV57771111, COSV57789371; called by muse, mutect2, varscan2
- EPHA5 | c.831C>T p.S277= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs377555731, COSV99901104; called by muse, mutect2, varscan2
- FBXL7 | c.955C>T p.L319= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV61645436; called by muse, mutect2, varscan2
- FBXO21 | c.966C>G p.V322= | Silent (SNP) | VAF 72/120 reads (60%) | catalogued as COSV57972642; called by muse, mutect2, varscan2
- GPR179 | c.6549C>T p.V2183= (on ENST00000621958; = p.V2182= on NM_001004334.4) | Silent (SNP) | VAF 36/160 reads (23%) | called by muse, mutect2, varscan2
- HECW2 | c.4587G>T p.G1529= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV53658185; called by muse, mutect2
- HNRNPR | c.1473C>T p.Y491= | Silent (SNP) | VAF 142/246 reads (58%) | catalogued as rs375738482; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1912C>T p.L638= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV56258576; called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2, varscan2
- KDM5B | c.3117C>G p.L1039= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV52507346; called by muse, mutect2, varscan2
- KDM6A | c.2319A>G p.L773= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs779685124, COSV65039897; called by muse, mutect2, varscan2
- KIAA1109 | c.5823C>T p.T1941= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs760846910, COSV52671363, COSV99145680; called by muse, mutect2, varscan2
- KIF17 | c.759G>A p.T253= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as rs200906557; called by muse, mutect2, varscan2
- LRFN5 | c.2058C>T p.V686= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs551906068, COSV53254629; called by muse, mutect2, varscan2
- LTBP1 | c.4818C>T p.P1606= (on ENST00000404816 / NM_206943.4; = p.P1280= on NM_000627.4) | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as COSV55378893; called by muse, mutect2, varscan2
- MUC16 | c.36855C>T p.T12285= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV67463223; called by muse, mutect2, varscan2
- NME8 | c.345T>C p.D115= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52249805; called by muse, mutect2, varscan2
- NOS3 | c.877C>T p.L293= | Silent (SNP) | VAF 80/225 reads (36%) | catalogued as COSV52489317; called by muse, mutect2, varscan2
- OR6C76 | c.882G>A p.V294= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV60389009; called by muse, mutect2, varscan2
- PARP9 | c.81G>A p.Q27= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs59755035, COSV64450631; called by muse, mutect2, varscan2
- PHF12 | c.2670G>A p.Q890= | Silent (SNP) | VAF 124/178 reads (70%) | catalogued as COSV60454265; called by muse, mutect2, varscan2
- PLEKHB2 | c.663C>T p.V221= (on ENST00000409279; = p.V220= on NM_017958.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 58/155 reads (37%) | catalogued as COSV52175736; called by muse, mutect2, varscan2
- PMEL | c.204C>T p.L68= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV62428694; called by muse, mutect2, varscan2
- PODN | c.1701G>T p.G567= (on ENST00000395871; = p.G519= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as COSV57013244; called by muse, mutect2, varscan2
- PPOX | c.1245C>T p.H415= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as COSV60527115; called by muse, varscan2
- SLC25A37 | c.678C>T p.V226= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV51563440, COSV51563948; called by muse, mutect2, varscan2
- SLC6A19 | c.1596C>T p.V532= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs748088574, COSV57251069; called by muse, mutect2, varscan2
- SLFN13 | c.1650G>A p.L550= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV99540535; called by muse, mutect2
- SPEN | c.3399T>C p.Y1133= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV65361342; called by muse, mutect2, varscan2
- TSPOAP1 | c.1770C>T p.L590= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs1567846796, COSV52108035; called by muse, mutect2, varscan2
- TXNRD2 | c.1113G>T p.A371= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV68691824, COSV68692046; called by muse, mutect2, varscan2
- UNC79 | c.7083C>G p.L2361= (on ENST00000393151 / NM_001346218.2; = p.L2184= on NM_020818.5) | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as rs1230020241, COSV56385894; called by muse, mutect2, varscan2
- ZNF135 | c.240C>T p.P80= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV57881789; called by muse, mutect2, varscan2
- ZNF248 | c.324C>T p.N108= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV61997637; called by muse, mutect2, varscan2
- ZNF618 | c.2763G>A p.G921= (on ENST00000374126 / NM_001318042.2; = p.G828= on NM_133374.2) | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV55920838; called by muse, mutect2, varscan2
- ASPSCR1 | c.1354-1120G>A | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV60715722; called by muse, mutect2, varscan2
- DLG2 | c.205-65663C>T | Intron (SNP) | VAF 51/194 reads (26%) | catalogued as rs762528558, COSV54641301; called by muse, varscan2
- MACF1 | c.15832-9871G>A | Intron (SNP) | VAF 38/69 reads (55%) | catalogued as rs376854788; called by muse, mutect2, varscan2
- MIR424 | n.15A>T | RNA (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- TPTE2 | c.1395+692C>T | Intron (SNP) | VAF 88/128 reads (69%) | called by muse, mutect2
- VPS11 | chr11:119069321 G>C | 5'Flank (SNP) | VAF 17/59 reads (29%) | catalogued as rs782263380, COSV100334040, COSV56185458; called by muse, mutect2, varscan2
